Somatic mutation profile of tumor specimen TCGA-IM-A3ED-01A (aliquot TCGA-IM-A3ED-01A-11D-A202-08) from TCGA case TCGA-IM-A3ED, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 58.3 years (21,278 days).
Specimen TCGA-IM-A3ED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e27ccec-40ca-413d-83ca-dfdea049569f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A3ED-10A (Blood Derived Normal), aliquot TCGA-IM-A3ED-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe24ba6d-429e-458d-9503-9d312c861d68

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLIC5 | c.673C>G p.L225V (on ENST00000185206 / NM_001370649.1; = p.L66V on NM_016929.5) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV51765963; called by muse, mutect2, varscan2
- LCA5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.178); catalogued as rs1472592808, COSV63973260; called by muse, mutect2, varscan2
- PRDM9 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1299187030, COSV57013972; called by muse, mutect2, varscan2
- ANK3 | c.5007G>A p.P1669= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs991201922, COSV55084366; called by muse, mutect2, varscan2
- CACNA1B | c.4554C>T p.C1518= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs575117282, COSV53150964, COSV53153369; called by muse, mutect2, varscan2
- EPHB6 | c.1791G>C p.V597= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV63893916; called by muse, mutect2, varscan2
- FBXW8 | c.384G>A p.V128= (on ENST00000309909; = p.V166= on NM_012174.1) | Silent (SNP) | VAF 83/285 reads (29%) | catalogued as COSV59303838; called by muse, mutect2, varscan2
- KLHL32 | c.888G>A p.G296= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV65115233; called by muse, mutect2, varscan2
- NOTCH3 | c.3762A>T p.P1254= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54652299; called by muse, mutect2, varscan2
